Gene-level copy-number profile of tumor specimen ALCH-B065-TTP1-A from ALCHEMIST case ALCH-B065, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.3 years (26,401 days).
Specimen ALCH-B065-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aeb90c4c-09c6-4423-b2b7-e810b08d6b79.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B065-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/7428b4d4-fbe0-4640-b200-31c4071a3709

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 242; copy number 2: 55,393; copy number 3: 1,969; copy number 4: 767; copy number 5: 27.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:119,165,034–119,673,453, 10 genes, copy number 5: MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23.
- chr8:124,044,395–124,372,692, 8 genes, copy number 5 (within-gene range 3–5): FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65.
- chr8:131,129,761–131,432,869, 3 genes, copy number 5: AC087341.1, AC104257.1, SNORA72.
- chr11:69,048,932–69,162,440, 4 genes, copy number 5 (within-gene range 3–5): TPCN2, AP003071.5, MIR3164, AP003071.1.
- chr11:79,966,805–79,989,630, 2 genes, copy number 5: AP001541.1, AP001284.1.

Autosomal genes at a single copy (total copy number 1): 242. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
